Somatic mutation profile of tumor specimen TCGA-S9-A6TY-01A (aliquot TCGA-S9-A6TY-01A-12D-A32B-08) from TCGA case TCGA-S9-A6TY, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 50.8 years (18,564 days).
Specimen TCGA-S9-A6TY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e779bfe-1236-462d-bccc-f872e810106a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6TY-10A (Blood Derived Normal), aliquot TCGA-S9-A6TY-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72174aed-7da0-41be-ae94-45116b2266eb

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 9, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS6 | c.1553G>T p.R518L | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV66862199; called by muse, mutect2, varscan2
- APAF1 | c.2516A>G p.H839R (on ENST00000551964 / NM_181861.2; = p.H828R on NM_013229.3) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1366254921, COSV100244335; called by muse, mutect2, varscan2
- BRD3 | c.692C>G p.P231R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100325388; called by muse, mutect2
- CXXC1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53276526; called by muse, mutect2, varscan2
- DMTN | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as COSV99742018; called by muse, mutect2, varscan2
- NIBAN1 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV100836516, COSV62284827; called by muse, mutect2, varscan2
- NLGN1 | c.1388A>G p.H463R | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as COSV100849818; called by muse, mutect2, varscan2
- OR5T1 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV100479160, COSV57301712, COSV57304173; called by muse, mutect2, varscan2
- SERPINB13 | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs374164881; called by muse, mutect2, varscan2
- SPRY4 | c.808C>T p.R270C (on ENST00000434127 / NM_001127496.3; = p.R293C on NM_030964.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1396279357, COSV100702226; called by muse, mutect2, varscan2
- THBS1 | c.2939G>A p.R980H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs201957578, COSV99528256; called by muse, mutect2, varscan2
- TMPRSS15 | c.211A>T p.N71Y | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV53046721; called by muse, mutect2, varscan2
- ATG4B | c.452_456del p.V151Efs*59 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- DNER | c.633G>A p.A211= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs200771367, COSV100519752; called by muse, mutect2, varscan2
- MAP2K7 | c.699G>A p.L233= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV101209113; called by muse, mutect2, varscan2
- SIRT1 | c.1341A>G p.P447= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV99281958; called by muse, mutect2, varscan2
- ST13 | c.885A>G p.G295= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV99344363; called by muse, mutect2, varscan2
- SVEP1 | c.6807G>A p.P2269= | Silent (SNP) | VAF 70/163 reads (43%) | catalogued as rs373455337; called by muse, mutect2, varscan2
- TEX55 | c.99C>T p.D33= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1354410121, COSV99817718; called by muse, mutect2, varscan2
- USP7 | c.2961G>A p.E987= | Silent (SNP) | VAF 10/273 reads (4%) | catalogued as COSV100784340; called by muse, mutect2
- ZFYVE19 | c.1068C>T p.D356= (on ENST00000355341 / NM_001077268.2; = p.D346= on NM_032850.5) | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs557912109, COSV54543056; called by muse, mutect2, varscan2
- ZNF132 | c.135A>G p.V45= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- GANAB | c.560+482A>G | Intron (SNP) | VAF 36/138 reads (26%) | catalogued as rs1453967105, COSV100648160; called by muse, mutect2, varscan2
